Somatic mutation profile of tumor specimen 0DOBTE from CCDI case PBCCJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.8 years (1,008 days).
Specimen 0DOBTE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e052ef2f-d52f-4eb2-89fe-70dd8a25fa7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOBST (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e66b4da-4ec9-4f62-ace5-3a44d08d17ac

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPS8L3 | c.1562G>A p.R521Q (on ENST00000361965 / NM_133181.4; = p.R491Q on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/417 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs778204016, COSV62610217; called by muse, mutect2, varscan2
- LUC7L3 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 197/705 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV53586716; called by muse, mutect2
- SDK2 | c.4571C>T p.P1524L | Missense Mutation (SNP) | VAF 210/753 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs763869312; called by muse, mutect2, varscan2
- SMARCB1 | c.705G>A p.W235* (on ENST00000263121; = p.W281* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 245/303 reads (81%) | catalogued as COSV54095433; called by muse, mutect2, varscan2
- USH2A | c.3132C>A p.V1044= | Silent (SNP) | VAF 36/758 reads (5%) | called by muse, mutect2
- ZNF521 | c.1158C>T p.A386= | Silent (SNP) | VAF 187/459 reads (41%) | catalogued as rs772847976; called by muse, mutect2, varscan2
- RGS12 | c.2761+47C>T | Intron (SNP) | VAF 82/277 reads (30%) | catalogued as rs370071279; called by muse, mutect2, varscan2
- SLC38A7 | c.-6G>A | 5'UTR (SNP) | VAF 12/314 reads (4%) | catalogued as rs1011488690; called by muse, mutect2
